Gene-level copy-number profile of tumor specimen TCGA-14-1452-01A from TCGA case TCGA-14-1452, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-14-1452-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9994a79a-8e8d-4c75-8e46-c617e69b6d01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1452-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd6b56b2-6ace-4c67-ac68-2601500cec18

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 4,734; copy number 2: 45,988; copy number 3: 8,626; copy number 4: 301; copy number 23: 29; copy number 29: 32; copy number 30: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-14-1452-01): tumor purity 0.74, ploidy 2.08, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–23,438,700, 77 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:2,234,195–3,118,049, 22 genes, copy number 29: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1.
- chr7:37,351,143–37,951,936, 10 genes, copy number 29 (within-gene range 2–29): RNU6-565P, RPS10P14, AC078843.1, Y_RNA, NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8.
- chr7:39,329,003–40,860,763, 29 genes, copy number 23 (within-gene range 2–23): SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1.
- chr7:53,002,420–55,260,256, 33 genes, copy number 30: AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 2,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
